Somatic mutation profile of tumor specimen TCGA-CM-6677-01A (aliquot TCGA-CM-6677-01A-11D-1835-10) from TCGA case TCGA-CM-6677, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.5 years (27,575 days).
Specimen TCGA-CM-6677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7658df4b-9613-4bf9-96a4-ce6e989f0ef2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6677-10A (Blood Derived Normal), aliquot TCGA-CM-6677-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0ad64b1-5f30-4c05-a5ed-703b9782d95b

The open-access MAF lists 152 somatic variants for this specimen: 112 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 35, Frame Shift Del 7, Nonsense Mutation 4, Splice Site 3, RNA 2, Splice Region 2, Intron 2, Frame Shift Ins 2, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 36/48 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1232G>A p.R411H (on ENST00000272895 / NM_173076.3; = p.R93H on NM_015657.3) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs768861556, COSV55947659, COSV99790235; called by muse, mutect2, varscan2
- ACVR2A | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296122552, COSV54021353; called by muse, mutect2, varscan2
- AGAP2 | c.1925C>A p.A642E (on ENST00000547588 / NM_001122772.2; = p.A306E on NM_014770.4) | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.171); catalogued as COSV99222539; called by muse, mutect2, varscan2
- AMPH | c.150+1G>T p.X50_splice | Splice Site (SNP) | VAF 57/217 reads (26%) | catalogued as COSV100341347; called by muse, mutect2, varscan2
- ARGFX | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs548796906, COSV57681504; called by muse, mutect2, varscan2
- ATP7A | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.135); catalogued as rs1557231591, COSV58451871; called by muse, mutect2, varscan2
- BABAM2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as rs1445947949, COSV56220125; called by muse, mutect2, varscan2
- CALN1 | c.332G>A p.R111H (on ENST00000329008 / NM_001017440.3; = p.R153H on NM_031468.4) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as rs764569419, COSV61118665; called by muse, mutect2, varscan2
- CASP4 | c.871G>C p.V291L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV101274120; called by muse, mutect2
- CCDC172 | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV60936982; called by muse, mutect2, varscan2
- CCIN | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV58723965; called by muse, mutect2, varscan2
- CDC73 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs754070093, COSV66464844; called by muse, mutect2, varscan2
- CDH22 | c.669C>T p.T223= | Splice Region (SNP) | VAF 21/65 reads (32%) | catalogued as COSV64836422; called by muse, mutect2, varscan2
- CEP350 | c.4030C>T p.R1344C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs755982034, COSV62598605; called by muse, mutect2, varscan2
- CHN2 | c.577-1G>A p.X193_splice | Splice Site (SNP) | VAF 28/210 reads (13%) | catalogued as COSV56086991; called by muse, mutect2, varscan2
- CHUK | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs148373303; called by muse, mutect2, varscan2
- CIART | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51743057; called by muse, mutect2, varscan2
- CLCN5 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs782060117, COSV56582195; called by muse, varscan2
- CLIP4 | c.1289C>A p.S430Y | Missense Mutation (SNP) | VAF 120/184 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60747288; called by muse, mutect2, varscan2
- CLNK | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.486); catalogued as COSV57010620; called by muse, mutect2, varscan2
- DCAF6 | c.1925A>C p.E642A (on ENST00000312263 / NM_001349778.1; = p.E662A on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); catalogued as COSV56574635; called by muse, mutect2, varscan2
- DDX60 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 97/164 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs574811561, COSV67094944; called by muse, mutect2, varscan2
- DNHD1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs372056276; called by muse, mutect2, varscan2
- ECEL1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV58811127; called by muse, mutect2, varscan2
- EDNRB | c.1424C>T p.A475V (on ENST00000377211 / NM_001201397.1; = p.A385V on NM_000115.5) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV100526388; called by muse, mutect2, varscan2
- EFNA2 | c.380C>G p.S127W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99288939; called by muse, mutect2, varscan2
- ENAM | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs776293682, COSV68535168; called by muse, mutect2, varscan2
- EPHB1 | c.67A>G p.M23V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV101212849; called by muse, mutect2, varscan2
- EXOSC8 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV53508576; called by muse, mutect2, varscan2
- FAM114A2 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV59455285; called by muse, mutect2, varscan2
- FAM133A | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV59073567, COSV59076903; called by muse, mutect2, varscan2
- FAM47A | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as COSV60493807, COSV60494503; called by muse, mutect2, varscan2
- FBXW7 | c.1537A>T p.R513W (on ENST00000281708 / NM_001349798.2; = p.R433W on NM_018315.5) | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV99655168; called by muse, mutect2, varscan2
- FCAR | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs143972917; called by muse, mutect2
- FCHO1 | c.791-2A>C p.X264_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99405897; called by mutect2, varscan2
- FREM1 | c.5684G>T p.R1895I | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66517272; called by muse, mutect2, varscan2
- GABRG2 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62715377, COSV62715450; called by muse, mutect2, varscan2
- GDF5 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.652); catalogued as COSV65499171; called by muse, mutect2, varscan2
- GINS3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs150647692; called by muse, mutect2, varscan2
- GLI3 | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs746798261, COSV67886970; called by muse, mutect2, varscan2
- GREB1 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs752977615, COSV52179947, COSV52182592; called by muse, mutect2, varscan2
- HSD17B6 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs148211848, COSV100444219; called by muse, mutect2, varscan2
- IL4I1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.556); catalogued as COSV99680498; called by muse, mutect2, varscan2
- JAKMIP2 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as rs781046321, COSV54597123; called by muse, mutect2, varscan2
- KCND3 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV56187673; called by muse, mutect2, varscan2
- KIRREL1 | c.1266C>G p.D422E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV63285157; called by muse, mutect2, varscan2
- KIRREL3 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69384088; called by muse, mutect2, varscan2
- LAMB1 | c.4978C>T p.R1660W | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs139866849; called by muse, mutect2, varscan2
- LAMB4 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV99223236; called by muse, mutect2
- LCOR | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs1252580231, COSV63629918; called by muse, mutect2, varscan2
- LCT | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); catalogued as rs746281788, COSV51464778; called by muse, mutect2, varscan2
- LIG4 | c.2042G>T p.R681I | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63596319; called by muse, mutect2, varscan2
- LRP2 | c.6897G>T p.K2299N | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55566082, COSV99787101; called by muse, mutect2, varscan2
- LRRC23 | c.52_55del p.E18Kfs*34 | Frame Shift Del (DEL) | VAF 49/88 reads (56%) | catalogued as COSV50386586; called by mutect2, pindel, varscan2
- MAGEL2 | c.3250A>T p.N1084Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); catalogued as rs377346630; called by muse, mutect2, varscan2
- MAML3 | c.2006G>T p.R669L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.891); catalogued as rs376108829, COSV59070771; called by muse, mutect2, varscan2
- MATN1 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.203); catalogued as COSV65650059; called by muse, mutect2, varscan2
- MCTP1 | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs145487587; called by muse, mutect2, varscan2
- MPP6 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56035098; called by muse, mutect2, varscan2
- MUC1 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58111220; called by muse, mutect2, varscan2
- MYO10 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72453836; called by muse, mutect2, varscan2
- MYO1E | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.429); catalogued as rs770956809, COSV55682245; called by muse, mutect2, varscan2
- MYT1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as rs751535010, COSV100114106, COSV60500674; called by muse, mutect2, varscan2
- NONO | c.767G>T p.R256I | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52135290; called by muse, mutect2, varscan2
- NUP210L | c.2087A>C p.E696A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55141058; called by muse, mutect2, varscan2
- OR12D2 | c.83T>A p.V28D | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV65826263; called by muse, mutect2, varscan2
- OR2T33 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100531710; called by muse, mutect2, varscan2
- OVCH1 | c.2033C>T p.S678L | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs1370810836, COSV58959200; called by muse, mutect2, varscan2
- PCDH10 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52103045; called by muse, mutect2
- PCDH12 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1378174359, COSV51520756; called by muse, mutect2, varscan2
- PCDHGA11 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV53894903; called by muse, mutect2, varscan2
- PCDHGA2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as rs770199497, COSV53894862; called by muse, mutect2, varscan2
- PCDHGB2 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53894880; called by muse, mutect2, varscan2
- PHAX | c.986T>G p.V329G | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV52549881; called by muse, mutect2, varscan2
- POU6F2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs768164622, COSV101302832, COSV68867184; called by muse, mutect2, varscan2
- PPP4R4 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV58551522; called by muse, mutect2, varscan2
- QRFPR | c.163A>T p.I55F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57675027; called by muse, mutect2, varscan2
- RALGAPB | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV99484883; called by muse, mutect2
- RASA3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.626); catalogued as rs779182286, COSV100480100; called by muse, mutect2
- RNF20 | c.1360A>G p.M454V | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV101206509; called by muse, mutect2, varscan2
- RNF213 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as rs549855016, COSV100173208; called by muse, mutect2, varscan2
- RPS6KA4 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1372636808, COSV53700523; called by muse, mutect2, varscan2
- RUBCN | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56362249; called by muse, mutect2, varscan2
- SCN10A | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs370009920; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELP | c.1652G>T p.R551I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV55247861, COSV55251762; called by muse, mutect2, varscan2
- SLC2A11 | c.463C>T p.R155* (on ENST00000345044 / NM_001024938.4; = p.R162* on NM_030807.5) | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs754365418, COSV55389559; called by muse, mutect2, varscan2
- SLC36A3 | c.489G>A p.Q163= | Splice Region (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100077427; called by muse, varscan2
- SLC4A1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs939561010, COSV52258041; called by muse, mutect2, varscan2
- SPEN | c.2759C>T p.S920F | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV101005062; called by muse, mutect2, varscan2
- ST3GAL4 | c.127A>T p.K43* (on ENST00000392669 / NM_001254758.1; = p.K39* on NM_006278.3) | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV57105797; called by muse, mutect2, varscan2
- TAF1L | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as rs1261064270, COSV54256533; called by muse, mutect2, varscan2
- TENM2 | c.1531C>T p.R511C (on ENST00000518659 / NM_001122679.2; = p.R279C on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs754385249, COSV69122362; called by muse, mutect2, varscan2
- TMC2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1035668319, COSV62649544; called by muse, varscan2
- TSC22D1 | c.1920G>A p.M640I | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1263061328, COSV71775083; called by muse, mutect2, varscan2
- TTLL1 | c.1066G>T p.V356F | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs763369910, COSV56737727, COSV56738414; called by muse, mutect2, varscan2
- UHRF1BP1L | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs1458058852, COSV54434276; called by muse, mutect2, varscan2
- UMOD | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56773269; called by muse, mutect2, varscan2
- VGLL1 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV101034579; called by mutect2, varscan2
- ZNF23 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs371943450; called by muse, mutect2, varscan2
- ZNF404 | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV100182387; called by muse, mutect2, varscan2
- ZNF471 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV57289743; called by muse, mutect2, varscan2
- AMER1 | c.939del p.F313Lfs*4 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | called by mutect2, pindel, varscan2
- APC | c.4738_4741del p.I1580Lfs*69 | Frame Shift Del (DEL) | VAF 35/63 reads (56%) | called by mutect2, pindel, varscan2
- DNAI3 | c.2479del p.I827Ffs*11 | Frame Shift Del (DEL) | VAF 63/164 reads (38%) | called by mutect2, varscan2
- GPR179 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2
- KIAA1958 | c.1543_1550delinsA p.W515Rfs*51 | Frame Shift Del (DEL) | VAF 32/50 reads (64%) | called by pindel, varscan2*
- NDUFB8 | c.154_156dup p.A52dup | In Frame Ins (INS) | VAF 16/34 reads (47%) | called by mutect2, varscan2
- NKX6-1 | c.830_833del p.E277Vfs*66 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- OR6C65 | c.305del p.L102* | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- SOX9 | c.788dup p.R264Qfs*32 | Frame Shift Ins (INS) | VAF 44/87 reads (51%) | called by mutect2, pindel, varscan2
- XRCC3 | c.228dup p.T77Hfs*28 | Frame Shift Ins (INS) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
- A1BG | c.1149C>T p.F383= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1397096664, COSV54049632; called by muse, mutect2, varscan2
- ANKRD11 | c.7344C>T p.I2448= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as rs773836911, COSV56354319; called by muse, mutect2, varscan2
- ASAH2 | c.1182T>C p.F394= | Silent (SNP) | VAF 44/395 reads (11%) | called by muse, varscan2
- BPI | c.807C>A p.P269= (on ENST00000262865; = p.P265= on NM_001725.3) | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV53403742; called by muse, mutect2, varscan2
- CACNA2D3 | c.762G>A p.P254= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs757954461, COSV55511572; called by muse, mutect2, varscan2
- CNTNAP2 | c.1677G>T p.V559= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100663996; called by muse, mutect2, varscan2
- CYB5R4 | c.1014G>A p.K338= | Silent (SNP) | VAF 91/125 reads (73%) | catalogued as rs1361707969, COSV63750039; called by muse, mutect2, varscan2
- DMD | c.2937C>T p.L979= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as rs774450833, COSV63733619; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EDNRB | c.459G>A p.A153= (on ENST00000377211 / NM_001201397.1; = p.A63= on NM_000115.5) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV57518710; called by muse, mutect2, varscan2
- EPB41 | c.738G>A p.L246= (on ENST00000343067 / NM_001166005.2; = p.L37= on NM_004437.4) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV58040428; called by muse, mutect2, varscan2
- FAAP20 | c.542G>A p.*181= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as rs376098288, COSV66031536; called by muse, mutect2, varscan2
- FN1 | c.888G>A p.P296= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs201079072, COSV60546128; called by muse, mutect2, varscan2
- GOT1 | c.1032C>T p.A344= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV65147020; called by muse, mutect2, varscan2
- INCENP | c.351C>T p.N117= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs754070097, COSV53913023; called by muse, mutect2
- MED12L | c.3990C>T p.L1330= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as COSV56367803; called by muse, mutect2, varscan2
- MUC16 | c.23325C>A p.T7775= | Silent (SNP) | VAF 71/432 reads (16%) | catalogued as rs747626109, COSV101198786; called by muse, mutect2, varscan2
- NFATC1 | c.588G>A p.P196= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs536523701, COSV53694642; called by muse, varscan2
- NLRP8 | c.78C>A p.P26= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV52583014; called by muse, mutect2, varscan2
- OTUD5 | c.42C>T p.A14= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV50233788; called by muse, mutect2
- PCDHGB2 | c.2028C>T p.S676= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV53894895; called by muse, mutect2, varscan2
- PRKAR1A | c.63C>T p.Y21= | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as rs777110464, CM087910, COSV62235097; ClinVar: likely benign; called by muse, mutect2, varscan2
- RABL3 | c.678G>A p.G226= | Silent (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- SHC4 | c.1827C>T p.S609= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs780366011, COSV60109258; called by muse, mutect2, varscan2
- SHPRH | c.279C>T p.S93= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs756323540, COSV51608268; called by muse, varscan2
- SI | c.4470T>C p.S1490= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV100014492; called by muse, mutect2, varscan2
- SIRPA | c.663C>T p.D221= | Silent (SNP) | VAF 88/345 reads (26%) | catalogued as rs754015483, COSV61536095; called by muse, mutect2, varscan2
- TEPP | c.639C>T p.S213= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs750815487, COSV52042531; called by muse, mutect2, varscan2
- TFDP3 | c.819C>T p.D273= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs762868660, COSV59535768; called by muse, mutect2, varscan2
- TLR5 | c.756A>G p.K252= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV60557839; called by muse, mutect2, varscan2
- TMC2 | c.177C>T p.R59= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV62649538; called by muse, varscan2
- VWC2L | c.357C>T p.H119= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs373003043; called by muse, mutect2, varscan2
- ZNF213 | c.798C>T p.S266= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1028762190, COSV67728359; called by muse, mutect2, varscan2
- ZNF492 | c.141T>C p.S47= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs1237209564, COSV101514061, COSV71761646; called by muse, mutect2
- ZNF703 | c.510C>T p.S170= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1471005790, COSV58998136; called by muse, varscan2
- ZNF782 | c.36C>T p.D12= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs759392365, COSV56651007; called by muse, mutect2, varscan2
- DCHS2 | n.4740C>A | RNA (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100601357, COSV61772559; called by muse, mutect2
- DLG2 | c.205-65794G>A | Intron (SNP) | VAF 27/53 reads (51%) | catalogued as rs552998302, COSV54619672; called by muse, mutect2, varscan2
- FAM183BP | n.941G>A | RNA (SNP) | VAF 15/61 reads (25%) | catalogued as rs560816398; called by muse, mutect2, varscan2
- OR1N2 | c.-23G>A | 5'UTR (SNP) | VAF 12/74 reads (16%) | catalogued as rs141317564; called by muse, mutect2, varscan2
- WNK1 | c.2140-2687C>T | Intron (SNP) | VAF 17/128 reads (13%) | catalogued as rs187534119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
